TCGA case TCGA-12-0772 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3726b315-6cf8-49a3-a581-b7f3f4ca6e16

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 46 years; Vital status: Dead; Days to death: 1,638 days (4.5 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 46.6 years (17,019 days); Year of diagnosis: 2003; Method of diagnosis: Excisional Biopsy; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 79 days; Days to treatment end: 120 days; Treatment dose: 5,940 cGy; Number of fractions: 29; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 79 days; Days to treatment end: 120 days; Number of cycles: 2; Treatment dose: 150 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide; Treatment intent type: Adjuvant; Days to treatment start: 120 days; Days to treatment end: 489 days (1.3 years); Number of cycles: 12; Treatment dose: 50 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Ridaforolimus; Initial disease status: Progressive Disease; Days to treatment start: 621 days (1.7 years); Days to treatment end: 670 days (1.8 years); Treatment dose: 13 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 670 days (1.8 years); Days to treatment end: 951 days (2.6 years); Number of cycles: 6; Treatment dose: 125 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Initial disease status: Progressive Disease; Days to treatment start: 951 days (2.6 years); Days to treatment end: 1,112 days (3.0 years); Number of cycles: 3; Treatment dose: 110 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 1,112 days (3.0 years); Days to treatment end: 1,174 days (3.2 years); Number of cycles: 2; Treatment dose: 50 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Initial disease status: Progressive Disease; Days to treatment start: 1,224 days (3.4 years); Days to treatment end: 1,265 days (3.5 years); Number of cycles: 1; Treatment dose: 83 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 1,307 days (3.6 years); Days to treatment end: 1,468 days (4.0 years); Treatment dose: 10 mg/kg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Initial disease status: Progressive Disease; Days to treatment start: 1,307 days (3.6 years); Days to treatment end: 1,468 days (4.0 years); Number of cycles: 5; Treatment dose: 100 mg; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 1,468 days (4.0 years); Days to treatment end: 1,526 days (4.2 years); Treatment dose: 10 mg.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Erlotinib Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 1,468 days (4.0 years); Days to treatment end: 1,526 days (4.2 years); Treatment dose: 150 mg/kg.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sirolimus; Initial disease status: Progressive Disease; Days to treatment start: 1,468 days (4.0 years); Days to treatment end: 1,526 days (4.2 years); Treatment dose: 10 mg.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 1,529 days (4.2 years); Days to treatment end: 1,616 days (4.4 years); Treatment dose: 10 mg/kg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide; Initial disease status: Progressive Disease; Days to treatment start: 1,529 days (4.2 years); Days to treatment end: 1,616 days (4.4 years); Number of cycles: 3; Treatment dose: 50 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Treatment dose: 1,800 cGy; Number of fractions: 1; Treatment anatomic sites: Locoregional Site.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 48.3 years (17,626 days); Days to diagnosis: 607 days (1.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 29 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.

Follow-up (5 entries)
- Day 607 (post initial treatment): Progression or recurrence: Yes; Days to progression: 607 days (1.7 years).
- Days to follow up: 1,615 days (4.4 years); Disease response: With Tumor.
- Days to follow up: 1,638 days (4.5 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Timepoint: Post Initial Treatment.
- Karnofsky performance status: 80; Timepoint: Prior to Adjuvant Therapy.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-12-0772-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 1; Shortest dimension: 0.4.
  Slide TCGA-12-0772-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0.
  Slide TCGA-12-0772-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 25; Percent stromal cells: 0.
- Sample TCGA-12-0772-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-12-0772-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Pre-Adjuvant Therapy.
- Drug treatment 1: Pharmaceutical therapy drug name: Temozolamide.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Pharmaceutical therapy drug name: Tarceva.
- Drug treatment 3: Pharmaceutical therapy drug name: ARIAD AP23573.
- Drug treatment 4: Pharmaceutical therapy drug name: VP-16.
- Drug treatment 5: Pharmaceutical therapy drug name: CPT-11.
- Drug treatment 5, Route of administrations: Route of administration: IV.
- Drug treatment 6: Pharmaceutical therapy drug name: Ccnu.
- Drug treatment 7: Pharmaceutical therapy drug name: Cytoxan.
- Drug treatment 10: Pharmaceutical therapy drug name: Avastin.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,638 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,638 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 607 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-12-0772-01A-01D-0333-01): tumor purity 0.75, ploidy 1.99, whole-genome doublings 0.
